TCGA case TCGA-EY-A1H0 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c71e0986-56c0-45f4-be8d-2236e4418604

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 57.3 years (20,937 days); Year of diagnosis: 2010; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IIIC2; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 588 days (1.6 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 3; Lymph nodes tested: 8.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 1; Lymph nodes tested: 4.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 23.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 315 days; Number of cycles: 6; Treatment dose: 3,380 mg; Prescribed dose: 6; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 315 days; Number of cycles: 6; Treatment dose: 1,660 mg; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 174 days; Days to treatment end: 176 days; Treatment dose: 540 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 202 days; Days to treatment end: 246 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 202 days; Days to treatment end: 241 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 244 days; Days to treatment end: 246 days; Treatment dose: 540 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Persistent Disease; Days to treatment start: 462 days (1.3 years); Number of cycles: 6; Treatment outcome: Treatment Ongoing; Prescribed dose: 80; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (3 entries)
- Days to follow up: 339 days; Disease response: Tumor Free.
- Days to follow up: 588 days (1.6 years); Disease response: With Tumor.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 1; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 90 kg; Height: 163 cm; BMI: 33.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EY-A1H0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 330 mg.
  Slide TCGA-EY-A1H0-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 30.
- Sample TCGA-EY-A1H0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EY-A1H0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: open.
- Follow-up form: Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; Pregnancies full term count: 1; History colorectal cancer: No; Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Taxol; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: persistent LAD.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 588 days; disease-specific survival: no event (censored), 588 days; progression-free interval: no event (censored), 588 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EY-A1H0-01A-11D-A13J-01): tumor purity 0.87, ploidy 2.15, whole-genome doublings 0.
